Gene-level copy-number profile of tumor specimen TCGA-QK-A6IJ-01A from TCGA case TCGA-QK-A6IJ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 71.1 years (25,966 days).
Specimen TCGA-QK-A6IJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.5baa782e-c117-4605-bd6f-fdb7c2e32a65.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QK-A6IJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ecd18066-730f-4eff-b5cd-3b99b998403e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,622; copy number 2: 29,539; copy number 3: 23,040; copy number 4: 2,861; copy number 5: 244; copy number 6: 63; copy number 7: 91; copy number 8: 38; copy number 9: 31; copy number 11: 41; copy number 12: 4; copy number 14: 120; copy number 17: 30; copy number 20: 1; copy number 23: 38; copy number 27: 40; copy number 48: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QK-A6IJ-01A-11D-A31K-01): tumor purity 0.32, ploidy 3.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 754 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:47,695,530–47,810,063, 1 gene, copy number 7 (within-gene range 3–7): MSH6.
- chr2:47,731,402–51,225,575, 38 genes, copy number 7: AC006509.1, U6, FBXO11, RPL36AP15, RPS27AP7, AC079807.1, AC092650.1, PPIAP62, VN1R18P, RN7SKP224, FOXN2, RNU4-49P, AC093635.1, PPP1R21, RNU6-282P, STON1, STON1-GTF2A1L, GTF2A1L, AC073082.1, TPT1P11, LHCGR, ELOBP3, AC009975.1, CTBP2P5, FSHR, MIR548BA, AC009975.2, RNU6-439P, AC009971.1, RPL7P13, SNORA75, NRXN1, AC068725.1, MTCO1P42, AC009234.1, MIR8485, AC007560.1, AC007682.1.
- chr2:51,441,959–51,455,913, 1 gene, copy number 7: AC007402.2.
- chr2:94,867,486–94,947,341, 1 gene, copy number 11 (within-gene range 3–11): AC097374.1.
- chr2:94,912,432–97,100,874, 99 genes, copy number 7–23 (broad region; genes not listed).
- chr8:46,028,804–50,796,692, 74 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr9:12,775,020–15,307,360, 36 genes, copy number 6–12: LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B.
- chr11:68,612,899–75,096,964, 224 genes, copy number 5–17 (within-gene range 4–17) (broad region; genes not listed).
- chr11:77,066,961–79,441,030, 47 genes, copy number 6 (within-gene range 4–6): CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1.
- chr11:99,020,949–103,895,271, 65 genes, copy number 7–48 (within-gene range 4–48) (broad region; genes not listed).
- chr11:103,945,548–103,946,546, 1 gene, copy number 7: AP003043.1.
- chr20:9,068,763–12,381,255, 47 genes, copy number 5–27 (within-gene range 2–27): PLCB4, LAMP5-AS1, LAMP5, PAK5, AL353612.2, AL353612.1, AL034427.1, PARAL1, ANKEF1, SNAP25-AS1, Metazoa_SRP, AL354824.1, AL354824.2, SNAP25, AL023913.1, HIGD1AP15, RPL23AP6, SDAD1P2, MKKS, AL034430.1, AL034430.2, SLX4IP, AL035456.1, JAG1, MIR6870, AL050403.2, LINC01752, AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1, AL049649.1, RPS11P1, AL109837.2, AL109837.3, AL109837.1, PGAM3P, AL161938.1, LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1, AL109838.1, AL136460.1, PA2G4P2.
- chr20:33,490,075–36,773,818, 120 genes, copy number 14 (within-gene range 4–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,235. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
